MMRF case MMRF_2518 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/90b367af-c095-4e7c-9ec6-ebe4356ea4b6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.1 years (31,093 days); ISS stage: III; Days to last known disease status: 658 days (1.8 years); Days to last follow up: 658 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 188 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 237 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -41 (ECOG 1): M Protein 3.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 534 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.5 mg/dL; Immunoglobulin G 28.2 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 5.99 µg/mL; Lactate Dehydrogenase 1.63 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 28 g/L; Total Protein 8.3 g/dL; Glucose 8.2 mmol/L; C-Reactive Protein 0.6 mg/dL.
- Day 50 (ECOG 2): M Protein 0.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.49 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 10.7 mmol/L.
- Day 147 (ECOG 3): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.616 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.077 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 8.2 mmol/L.
- Day 232 (ECOG 3): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.506 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 7.92 mmol/L.
- Day 328 (ECOG 2): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.625 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 2.65 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.17 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 42.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 6 mmol/L.
- Day 412 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.2 g/dL; Glucose 6.77 mmol/L.
- Day 496 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.706 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.157 mg/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5 g/dL; Glucose 5.17 mmol/L.
- Day 571 (ECOG 3): M Protein 0 g/dL; Immunoglobulin G 3.1 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.4 g/dL; Glucose 5.61 mmol/L.
- Day 658 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.681 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -41: Weight: 83 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2518_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -41 days.
- Sample MMRF_2518_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -41 days.
